Somatic mutation profile of tumor specimen TCGA-FS-A1Z3-06A (aliquot TCGA-FS-A1Z3-06A-11D-A197-08) from TCGA case TCGA-FS-A1Z3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.9 years (26,638 days).
Specimen TCGA-FS-A1Z3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a0da4a6-0c7d-47c1-8f06-2cccaa535023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1Z3-10A (Blood Derived Normal), aliquot TCGA-FS-A1Z3-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deb9d4c9-706e-4b16-aacf-ad67671677f8

The open-access MAF lists 1,233 somatic variants for this specimen: 827 protein-altering or splice-affecting, 376 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 750, Silent 376, Nonsense Mutation 51, Intron 14, Splice Region 11, RNA 9, Splice Site 6, Frame Shift Del 5, 3'UTR 3, 3'Flank 2, In Frame Ins 2, Frame Shift Ins 1.

Variants (750 of 1,233; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTK | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 46/54 reads (85%) | catalogued as rs1555980049, CM960198, COSV58124122; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EPHA3 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 49/111 reads (44%) | hotspot (GDC flag); catalogued as rs770780950, COSV60693907; called by muse, mutect2, varscan2
- LPA | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 67/160 reads (42%) | catalogued as rs121912503, COSV60296281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 118/130 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PSG4 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 113/346 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.29); PolyPhen possibly damaging (0.854); catalogued as COSV54932991; called by muse, mutect2, varscan2
- ABCA4 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT tolerated (0.85); PolyPhen benign (0.011); catalogued as rs755640766, COSV64678797; called by muse, mutect2, varscan2
- ABCA6 | c.4667T>C p.L1556P | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173748238, COSV52645833; called by muse, mutect2, varscan2
- ABCC6 | c.4424G>A p.G1475E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52748306; called by muse, mutect2, varscan2
- ABHD5 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50007123; called by muse, mutect2, varscan2
- AC005833.1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.97); catalogued as COSV52899198, COSV52899545; called by muse, mutect2, varscan2
- ACKR3 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV56024200; called by muse, mutect2, varscan2
- ACMSD | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV51610068; called by muse, mutect2, varscan2
- ACSL3 | c.830T>C p.L277S | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV62484986; called by muse, mutect2, varscan2
- ACSM2A | c.420G>A p.M140I (on ENST00000219054; = p.M61I on NM_001308169.2) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV54584565; called by muse, mutect2, varscan2
- ACSS3 | c.1680T>G p.N560K | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54102481; called by muse, mutect2, varscan2
- ADAM18 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55856211; called by muse, mutect2, varscan2
- ADAM23 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV52211747; called by muse, mutect2, varscan2
- ADAM23 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV52232018; called by muse, mutect2, varscan2
- ADAMTS12 | c.4366G>A p.D1456N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV61260420; called by muse, mutect2, varscan2
- ADAMTS18 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770516167, COSV51399705; called by muse, mutect2, varscan2
- ADAMTS20 | c.2998C>T p.R1000C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as rs369101503; called by muse, mutect2, varscan2
- ADAMTS20 | c.2734G>A p.G912S | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.216); catalogued as rs770507465, COSV67140526; called by muse, mutect2, varscan2
- ADAP1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 568/611 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs1177532887, COSV56217993; called by muse, mutect2, varscan2
- ADGRL2 | c.2968T>A p.F990I (on ENST00000370717 / NM_001366005.1; = p.F977I on NM_012302.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54691726; called by muse, mutect2, varscan2
- ADH1B | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 116/258 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59294987; called by muse, mutect2, varscan2
- AFM | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs1327023385, COSV56922522; called by muse, mutect2, varscan2
- AGL | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs777738895, COSV54048606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGXT2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV51491337; called by muse, mutect2, varscan2
- AKAP3 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs191710575, COSV57413363; called by muse, mutect2, varscan2
- AKAP6 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV55235433; called by muse, mutect2, varscan2
- ALB | c.1716G>A p.M572I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV55743196; called by muse, mutect2, varscan2
- ALDH1L2 | c.1351T>C p.F451L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV51560316; called by muse, mutect2, varscan2
- ALG11 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101584369, COSV73000811; called by muse, mutect2, varscan2
- ALPG | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776029863, COSV54968462; called by muse, mutect2, varscan2
- ALPK2 | c.4514C>T p.P1505L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV64496931; called by muse, mutect2, varscan2
- ALPK2 | c.2645G>A p.G882D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as COSV64497752; called by muse, mutect2, varscan2
- ALPL | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV66376068; called by muse, mutect2, varscan2
- ALS2 | c.3965C>T p.A1322V | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV51893499, COSV99969896; called by muse, mutect2, varscan2
- ALYREF | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1463690086, COSV58669299; called by muse, mutect2, varscan2
- AMY1B | c.879G>A p.K293= | Splice Region (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100375574; called by mutect2, varscan2
- AMZ1 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 30/381 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV56689324; called by muse, mutect2
- ANGPT4 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as rs753031251, COSV67923044; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100628672; called by mutect2, varscan2
- ANKS1B | c.3624A>T p.K1208N (on ENST00000547776 / NM_152788.4; = p.K374N on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59125520; called by muse, mutect2, varscan2
- AOAH | c.1514T>G p.F505C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV51751340; called by muse, varscan2
- APCS | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1444519185, COSV54817394; called by muse, mutect2, varscan2
- APOC1 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 229/263 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs773324927, COSV52992438; called by muse, varscan2
- ARAP2 | c.4121G>A p.W1374* | Nonsense Mutation (SNP) | VAF 37/110 reads (34%) | catalogued as COSV58293222; called by muse, mutect2, varscan2
- ARFGEF3 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs374061664; called by muse, mutect2, varscan2
- ARHGAP20 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 72/97 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52814905; called by muse, mutect2, varscan2
- ARHGDIB | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs759402191, COSV57455700; called by muse, mutect2, varscan2
- ARHGEF11 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV63814187; called by muse, mutect2, varscan2
- ARHGEF17 | c.4736C>T p.P1579L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs777259994, COSV55233187; called by muse, mutect2, varscan2
- ARID1B | c.5719G>T p.E1907* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as rs1554237641, COSV51682987; called by muse, mutect2, varscan2
- ARID2 | c.1787T>A p.V596E | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57613137, COSV57615932; called by muse, mutect2, varscan2
- ARMC12 | c.431G>A p.R144K (on ENST00000373866 / NM_001286574.2; = p.R171K on NM_145028.5) | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as rs867909477, COSV55361939; called by muse, mutect2, varscan2
- ARMC4 | c.569T>A p.I190N | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV53468922; called by muse, mutect2, varscan2
- ARSH | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 46/56 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781068827, COSV101140004; called by muse, mutect2, varscan2
- ARVCF | c.1964T>C p.F655S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV54270505; called by muse, mutect2
- ASB15 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.261); catalogued as COSV51929655; called by muse, mutect2, varscan2
- ASCC3 | c.6322C>T p.P2108S | Missense Mutation (SNP) | VAF 104/208 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV64981711; called by muse, mutect2, varscan2
- ASTN2 | c.1537C>T p.L513F (on ENST00000313400 / NM_001365069.1; = p.L462F on NM_014010.5) | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57821239; called by muse, mutect2, varscan2
- ASXL2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV55468830, COSV55469533; called by muse, mutect2, varscan2
- ASXL3 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.02); catalogued as COSV52464752; called by muse, mutect2, varscan2
- ASXL3 | c.5918G>A p.G1973E | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV52481366; called by muse, mutect2, varscan2
- ASXL3 | c.6727G>T p.A2243S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.96); catalogued as COSV99326916; called by muse, mutect2, varscan2
- ASXL3 | c.6728C>T p.A2243V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99326918; called by muse, mutect2, varscan2
- ATCAY | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs763099910, COSV56654027; called by muse, mutect2, varscan2
- ATCAY | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56659656; called by muse, mutect2, varscan2
- ATL1 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63297829; called by muse, mutect2, varscan2
- ATP10A | c.2017C>A p.Q673K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.026); catalogued as COSV63525674; called by muse, mutect2, varscan2
- ATP10B | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165563130, COSV59165831; called by muse, mutect2, varscan2
- ATP10D | c.1748A>T p.Y583F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as COSV56713791; called by muse, mutect2, varscan2
- ATP10D | c.4262C>T p.S1421F | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV56700499; called by muse, mutect2, varscan2
- ATP11C | c.2838G>A p.M946I | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV59575515; called by muse, mutect2, varscan2
- ATP13A5 | c.3194G>A p.G1065E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60876221; called by muse, mutect2, varscan2
- ATP2B1 | c.3413G>A p.R1138K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.173); catalogued as COSV53813711; called by muse, mutect2, varscan2
- AVIL | c.1110T>G p.D370E | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57684085; called by muse, mutect2
- AWAT1 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV65739156; called by muse, mutect2, varscan2
- AXDND1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62641537, COSV62649476; called by muse, mutect2, varscan2
- BAX | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 77/86 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV53171963; called by muse, mutect2, varscan2
- BAZ2B | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV58610932; called by muse, mutect2, varscan2
- BCAS3 | c.1721C>T p.S574L (on ENST00000390652 / NM_001353144.2; = p.S559L on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs959545152, COSV66783081; called by muse, mutect2, varscan2
- BICRAL | c.3200C>T p.S1067F | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58408747; called by muse, mutect2, varscan2
- BIRC6 | c.9952C>T p.P3318S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.802); catalogued as rs1211095131, COSV70206894; called by muse, mutect2, varscan2
- BLNK | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 53/70 reads (76%) | SIFT tolerated (0.31); PolyPhen benign (0.155); catalogued as COSV56415436; called by muse, mutect2, varscan2
- BMPER | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51832830; called by muse, mutect2, varscan2
- BMS1 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV65735731; called by muse, mutect2, varscan2
- BPIFC | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1222759178, COSV55915784; called by muse, mutect2, varscan2
- BPTF | c.4044T>G p.S1348R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV58848133; called by muse, mutect2, varscan2
- BRINP2 | c.1507C>T p.L503F | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV64180720; called by muse, mutect2, varscan2
- BRPF1 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.744); catalogued as COSV100121436; called by muse, mutect2, varscan2
- BTBD10 | c.875T>C p.M292T | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV53401935; called by muse, mutect2, varscan2
- BTBD11 | c.2920C>T p.Q974* (on ENST00000280758 / NM_001018072.2; = p.Q511* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs267603283, COSV55039078; called by muse, mutect2, varscan2
- BTBD16 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as COSV53267448; called by muse, mutect2, varscan2
- C16orf70 | c.251T>C p.L84S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV54629611; called by muse, mutect2, varscan2
- C17orf80 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52148995; called by muse, mutect2, varscan2
- C18orf21 | c.637T>C p.S213P | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV52450062; called by muse, mutect2, varscan2
- C1orf158 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.668); catalogued as COSV55348175; called by muse, mutect2, varscan2
- C6 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54707573; called by muse, mutect2, varscan2
- C7 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV57481990; called by muse, varscan2
- C8B | c.741A>C p.K247N | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV64779919; called by muse, mutect2, varscan2
- C8orf34 | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV61398824; called by muse, mutect2, varscan2
- C8orf34 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.109); catalogued as rs1298029851, COSV57413246; called by muse, mutect2
- CACNA1E | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV62387196; called by muse, mutect2, varscan2
- CACNA1E | c.6563G>A p.G2188E (on ENST00000367573 / NM_001205293.3; = p.G2145E on NM_000721.4) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV62389127, COSV62424046; called by muse, mutect2, varscan2
- CACNA1E | c.6791A>G p.N2264S (on ENST00000367573 / NM_001205293.3; = p.N2221S on NM_000721.4) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.754); catalogued as COSV62432343; called by muse, mutect2, varscan2
- CADPS2 | c.2923C>T p.P975S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV57388462; called by muse, mutect2, varscan2
- CALHM6 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63991832; called by muse, mutect2, varscan2
- CALM1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.194); catalogued as COSV63663815; called by muse, mutect2, varscan2
- CAMK1D | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 166/217 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66620544; called by muse, mutect2, varscan2
- CAMK2B | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1489151076, COSV51663039; called by muse, mutect2, varscan2
- CAPN3 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58821778; called by muse, mutect2, varscan2
- CASP8 | c.1085G>A p.G362E (on ENST00000432109 / NM_033355.3; = p.G379E on NM_001228.4) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51860200; called by muse, varscan2
- CCDC186 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65159902; called by muse, mutect2, varscan2
- CCDC30 | c.2270G>A p.S757N (on ENST00000340612; = p.S714N on NM_001080850.3) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV59246674; called by muse, mutect2, varscan2
- CCDC88C | c.4841C>T p.A1614V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV57798209; called by muse, mutect2, varscan2
- CCDC88C | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV66236103; called by muse, mutect2, varscan2
- CCIN | c.1604C>T p.T535I | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58725831; called by muse, mutect2, varscan2
- CCL27 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV52405876; called by muse, mutect2, varscan2
- CCNP | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as COSV55688908; called by muse, mutect2, varscan2
- CD101 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1488414807, COSV56721576; called by muse, mutect2, varscan2
- CD163 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV63131777; called by muse, mutect2, varscan2
- CD1A | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.416); catalogued as rs781773699, COSV56864542; called by muse, mutect2, varscan2
- CD1E | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV63773245; called by muse, mutect2, varscan2
- CD300E | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60790191; called by muse, mutect2, varscan2
- CD40 | c.477A>T p.E159D | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV64848316; called by muse, mutect2, varscan2
- CDH10 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as COSV100049556, COSV52573536; called by muse, mutect2, varscan2
- CDH12 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66452776; called by muse, mutect2, varscan2
- CDH6 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.812); catalogued as rs771406443, COSV54069300; called by muse, mutect2, varscan2
- CDYL | c.319C>T p.H107Y (on ENST00000328908 / NM_001368125.1; = p.H53Y on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV59362069; called by muse, mutect2, varscan2
- CENPJ | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV67884382; called by muse, mutect2, varscan2
- CENPP | c.116T>C p.F39S | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs767927228, COSV65042167; called by muse, mutect2, varscan2
- CEP164 | c.3887C>T p.S1296F | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1161934779, COSV54046953; called by muse, mutect2, varscan2
- CEP192 | c.4927G>A p.G1643R | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58071284; called by muse, mutect2, varscan2
- CFAP299 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs1240300099, COSV63875165, COSV63887963; called by muse, mutect2, varscan2
- CFAP47 | c.1237T>C p.F413L | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.755); catalogued as COSV52892553; called by muse, mutect2, varscan2
- CFAP92 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs757878053, COSV54049155; called by muse, mutect2, varscan2
- CFH | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs746222626, CM1512032, COSV62778762; called by muse, mutect2, varscan2
- CHD4 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 43/89 reads (48%) | catalogued as COSV58893592; called by muse, mutect2, varscan2
- CHD5 | c.3595G>A p.E1199K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52412463, COSV52426373; called by muse, mutect2, varscan2
- CHRM4 | c.1231C>T p.L411F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs746016944, COSV58991983; called by muse, mutect2, varscan2
- CHRNA9 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs773078059, COSV59576424; called by muse, mutect2, varscan2
- CILP | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV56028385; called by muse, mutect2, varscan2
- CLPTM1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 521/605 reads (86%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV61612944; called by muse, mutect2, varscan2
- CLSTN2 | c.180T>G p.I60M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV71725525; called by muse, mutect2, varscan2
- CMBL | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.119); catalogued as COSV56985517; called by muse, mutect2, varscan2
- CMTM5 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs775522723, COSV59307957; called by muse, mutect2, varscan2
- CMTR1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1237491818, COSV65091882; called by muse, mutect2, varscan2
- CMYA5 | c.6706C>T p.H2236Y | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV71409968; called by muse, mutect2, varscan2
- CNDP2 | c.1220T>C p.V407A | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV60841854; called by muse, mutect2, varscan2
- CNNM2 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV63996513; called by muse, mutect2, varscan2
- CNTN6 | c.2828G>A p.R943Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs758555625, COSV100610346, COSV100611951; called by muse, mutect2, varscan2
- CNTNAP2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as rs868783000, COSV62173390; called by muse, mutect2, varscan2
- CNTNAP3 | c.2789G>A p.G930E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99905755; called by muse, mutect2, varscan2
- COL23A1 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs757167147, COSV66799597; called by muse, mutect2, varscan2
- COL24A1 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs576997115, COSV65311512; called by muse, mutect2, varscan2
- COL2A1 | c.140G>A p.W47* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV61534970; called by muse, mutect2, varscan2
- COL3A1 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV58597598; called by muse, mutect2, varscan2
- COL3A1 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs745961376, COSV58597612; called by muse, mutect2, varscan2
- COL3A1 | c.3401G>A p.G1134E | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58597624; called by muse, mutect2, varscan2
- COL3A1 | c.3601G>A p.G1201R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.186); catalogued as COSV58595236; called by muse, mutect2, varscan2
- COL4A3 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780287240, COSV67421050; called by muse, mutect2, varscan2
- COL4A4 | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as rs200714000, COSV61632466; called by muse, mutect2, varscan2
- COL4A5 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 88/124 reads (71%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV60363263; called by muse, mutect2, varscan2
- COL4A6 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT tolerated (0.61); PolyPhen benign (0.043); catalogued as rs868757997, COSV57869489; called by muse, mutect2, varscan2
- COL7A1 | c.2108C>T p.T703I | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV60403991; called by muse, mutect2, varscan2
- COPS2 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54647830; called by muse, mutect2, varscan2
- CORO1C | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV54599261; called by muse, mutect2, varscan2
- CPA4 | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV55985307; called by muse, mutect2, varscan2
- CPNE4 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs866070002, COSV101456689, COSV70200764; called by muse, mutect2, varscan2
- CR1L | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as rs774250991, COSV54332024; called by muse, mutect2, varscan2
- CR2 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as rs374421007; called by muse, mutect2, varscan2
- CREB5 | c.179C>T p.P60L (on ENST00000357727 / NM_182898.4; = p.P53L on NM_004904.3) | Missense Mutation (SNP) | VAF 283/480 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760077074, COSV63220219; called by muse, mutect2, varscan2
- CRYBB2 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV68005851; called by muse, mutect2, varscan2
- CSMD1 | c.6059T>A p.F2020Y (on ENST00000520002; = p.F2019Y on NM_033225.6) | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59391525; called by muse, mutect2, varscan2
- CSMD1 | c.3443G>A p.R1148Q (on ENST00000520002; = p.R1147Q on NM_033225.6) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs766089311, COSV59289215; called by muse, mutect2, varscan2
- CSMD1 | c.3148G>A p.G1050R (on ENST00000520002; = p.G1049R on NM_033225.6) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1294364594, COSV59391582; called by muse, mutect2, varscan2
- CSMD2 | c.3649C>T p.P1217S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV53913405, COSV99592974; called by muse, mutect2, varscan2
- CSRNP1 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as COSV56187674; called by muse, mutect2, varscan2
- CST9 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1005182297, COSV65402629; called by muse, mutect2, varscan2
- CTC1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV59853480; called by muse, mutect2, varscan2
- CTCFL | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as rs765675257, COSV54773669; called by muse, mutect2, varscan2
- CXorf58 | c.191T>A p.L64H | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64858896; called by muse, mutect2, varscan2
- CYLC2 | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 16/26 reads (62%) | catalogued as COSV66339864; called by muse, mutect2, varscan2
- CYP3A4 | c.801C>T p.H267= | Splice Region (SNP) | VAF 21/49 reads (43%) | catalogued as COSV60504511; called by muse, mutect2, varscan2
- CYP4B1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as COSV54726606; called by muse, mutect2, varscan2
- CYP4Z1 | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as rs149156333; called by muse, mutect2, varscan2
- CYP4Z1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV61965435; called by muse, mutect2, varscan2
- CYRIA | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV62867467; called by muse, mutect2, varscan2
- DAAM2 | c.2062T>C p.L688= | Splice Region (SNP) | VAF 19/60 reads (32%) | catalogued as COSV51421186; called by muse, mutect2, varscan2
- DARS1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779321480, COSV51539557; called by muse, mutect2, varscan2
- DAXX | c.1220A>T p.D407V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV56473211; called by muse, mutect2, varscan2
- DAXX | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.212); catalogued as COSV56473223; called by muse, mutect2, varscan2
- DBH | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0.05); PolyPhen benign (0.193); catalogued as COSV55040911; called by muse, mutect2, varscan2
- DCAF12L1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV64422866; called by muse, mutect2, varscan2
- DCAF4L2 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60483095; called by muse, mutect2, varscan2
- DCAF4L2 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV60483110; called by muse, mutect2, varscan2
- DCST1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV55063265, COSV55063820; called by muse, mutect2, varscan2
- DDC | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866336739, COSV63563694; called by muse, mutect2, varscan2
- DDX28 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV60106038; called by muse, mutect2, varscan2
- DDX3X | c.1591A>G p.T531A (on ENST00000399959; = p.T532A on NM_001356.5) | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67863354; called by muse, mutect2, varscan2
- DDX60 | c.3848G>A p.G1283E | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67099579; called by muse, mutect2, varscan2
- DENND2A | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV52060062; called by muse, mutect2, varscan2
- DENND5A | c.2243G>A p.W748* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as rs1554915423, COSV60238288; called by muse, mutect2, varscan2
- DGCR2 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 153/371 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV54222822; called by muse, mutect2, varscan2
- DHRS9 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV59139996; called by muse, mutect2, varscan2
- DIO3 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.343); catalogued as COSV63774726; called by muse, mutect2, varscan2
- DISP1 | c.3464C>T p.S1155F | Missense Mutation (SNP) | VAF 468/775 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV52664791; called by muse, mutect2, varscan2
- DISP2 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51145955; called by muse, mutect2, varscan2
- DLG5 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.697); catalogued as COSV64950236; called by muse, mutect2, varscan2
- DLL4 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs772439875, COSV51069174; called by muse, mutect2, varscan2
- DMBT1 | c.6623G>A p.R2208Q (on ENST00000338354 / NM_001377530.1; = p.R1451Q on NM_004406.3) | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs147966171, COSV57565233; called by muse, mutect2, varscan2
- DMPK | c.1262T>A p.M421K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV52182822; called by muse, mutect2, varscan2
- DNAH10 | c.12622G>A p.E4208K (on ENST00000409039; = p.E4147K on NM_207437.3) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs775611601, COSV69003454; called by muse, mutect2, varscan2
- DNAH17 | c.5060G>A p.W1687* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV67761920; called by muse, mutect2, varscan2
- DNAH2 | c.9163G>A p.E3055K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV66728206; called by muse, mutect2, varscan2
- DNAH3 | c.6472G>A p.E2158K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760584539, COSV54532648; called by muse, mutect2, varscan2
- DNAH5 | c.12622A>T p.I4208F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54255738; called by muse, mutect2
- DNAH5 | c.9124C>T p.R3042* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as rs760595654, COSV54246587, COSV54254136; called by muse, mutect2, varscan2
- DNAH5 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140968268, COSV54202500; called by muse, mutect2, varscan2
- DNAH7 | c.9334G>A p.D3112N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56789380; called by muse, mutect2, varscan2
- DNAH7 | c.7022G>A p.G2341E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56789396; called by muse, mutect2, varscan2
- DNAH9 | c.6602G>A p.W2201* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as rs1225324996, COSV52379388; called by muse, mutect2, varscan2
- DNAJC13 | c.3325A>G p.I1109V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs780007049, COSV53459133; called by muse, mutect2, varscan2
- DNTT | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV64523460, COSV64523781; called by muse, mutect2, varscan2
- DOP1B | c.3286C>T p.P1096S | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV67696702; called by muse, mutect2, varscan2
- DOT1L | c.2225C>A p.P742H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs1366871233, COSV67113790; called by muse, mutect2, varscan2
- DPPA3 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV61503717; called by muse, mutect2, varscan2
- DSC1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV57152279; called by muse, mutect2, varscan2
- DSC2 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as COSV51866853; called by muse, mutect2, varscan2
- DSCAM | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV68024455; called by muse, mutect2, varscan2
- DSG2 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs374875442, CM1110701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSG3 | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as rs747842021, COSV57125290; called by muse, mutect2, varscan2
- DSG3 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs866853810, COSV57129277; called by muse, mutect2, varscan2
- DSG4 | c.87G>A p.V29= | Splice Region (SNP) | VAF 29/54 reads (54%) | catalogued as CD078493, COSV57398370; called by muse, mutect2, varscan2
- DSP | c.6635G>A p.G2212E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65792198; called by muse, mutect2, varscan2
- EDDM3A | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV58795494; called by muse, mutect2, varscan2
- EDDM3A | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as rs199609364, COSV58795019; called by muse, mutect2, varscan2
- EEPD1 | c.1139A>C p.K380T | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV54203650; called by muse, mutect2, varscan2
- EFCAB3 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV59505316; called by muse, mutect2, varscan2
- EGFLAM | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59319440; called by muse, mutect2, varscan2
- EHBP1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV50441701; called by muse, mutect2, varscan2
- EMB | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV57480680; called by muse, mutect2, varscan2
- EML5 | c.3946C>T p.R1316C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763841931, COSV61348097; called by muse, mutect2, varscan2
- ENOPH1 | c.242A>C p.N81T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56732491; called by muse, mutect2, varscan2
- EPB41L2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100440320, COSV61353986; called by muse, mutect2, varscan2
- EPB42 | c.2015T>A p.M672K (on ENST00000441366 / NM_001114134.2; = p.M702K on NM_000119.3) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV55747576; called by muse, mutect2, varscan2
- EPHA6 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750297483, COSV67556787; called by muse, mutect2, varscan2
- EPHB4 | c.2543C>A p.S848Y | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV62270770; called by muse, mutect2, varscan2
- EPPK1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV73262439; called by muse, mutect2
- ERICH3 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 80/102 reads (78%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as rs371417037, COSV100446075, COSV58602494; called by muse, mutect2, varscan2
- F2R | c.311T>A p.F104Y | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59930325; called by muse, mutect2, varscan2
- FABP1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55559621; called by muse, mutect2, varscan2
- FAM135B | c.3449G>A p.G1150E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1234932582, COSV52756291; called by muse, mutect2, varscan2
- FAM155A | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs921482748, COSV65578670; called by muse, mutect2, varscan2
- FAM180A | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.357); catalogued as COSV58529484; called by muse, mutect2, varscan2
- FAM184A | c.744T>A p.Y248* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV58859203; called by muse, mutect2, varscan2
- FAM214A | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV55927566; called by muse, mutect2, varscan2
- FAM47A | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV60500189; called by muse, mutect2, varscan2
- FAM83B | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV60927489; called by muse, mutect2, varscan2
- FAP | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs762738740, CM145280, COSV51860775; called by muse, mutect2
- FARS2 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV51176902; called by muse, mutect2, varscan2
- FASTKD3 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52947155; called by muse, mutect2, varscan2
- FAT4 | c.10627C>T p.Q3543* | Nonsense Mutation (SNP) | VAF 51/134 reads (38%) | catalogued as COSV58711527; called by muse, mutect2, varscan2
- FAT4 | c.14401C>T p.R4801C | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199895179, COSV58671338; called by muse, mutect2, varscan2
- FBXO4 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs768661903, COSV55854448; called by muse, mutect2, varscan2
- FCAMR | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs765999152, COSV100249837, COSV61367639; called by muse, mutect2, varscan2
- FCRL1 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 73/134 reads (54%) | catalogued as COSV63827816; called by muse, mutect2, varscan2
- FER1L6 | c.2956C>T p.R986W | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767953676, COSV67553076; called by muse, mutect2, varscan2
- FGD1 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV64309771; called by muse, mutect2, varscan2
- FHDC1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs546434622, COSV52603594; called by muse, mutect2, varscan2
- FKBP5 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61884103; called by muse, mutect2, varscan2
- FMO4 | c.1652A>T p.Y551F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV63002011; called by muse, mutect2, varscan2
- FOXP4 | c.2011G>A p.E671K (on ENST00000307972 / NM_001012426.1; = p.E658K on NM_138457.3) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs1205590462, COSV57224044; called by muse, mutect2, varscan2
- FPR1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 144/161 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs551338523, COSV59052578; called by muse, mutect2, varscan2
- FRG2C | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.953); catalogued as rs1183970282; called by muse, mutect2, varscan2
- FSCN2 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs782272650, COSV58369595; called by muse, mutect2
- FSTL4 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV54787501; called by muse, mutect2, varscan2
- FSTL5 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60219307; called by muse, mutect2, varscan2
- FUCA1 | c.1160+2T>G p.X387_splice | Splice Site (SNP) | VAF 42/48 reads (88%) | catalogued as COSV65699682; called by muse, mutect2, varscan2
- FZD1 | c.1927G>A p.G643R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV55313679; called by muse, mutect2, varscan2
- GAB2 | c.1534C>T p.P512S (on ENST00000361507 / NM_080491.3; = p.P474S on NM_012296.3) | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs767435145, COSV60870131; called by muse, mutect2, varscan2
- GABRQ | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 62/82 reads (76%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV64781024; called by muse, mutect2, varscan2
- GALNT13 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV67215769; called by muse, mutect2, varscan2
- GALNT13 | c.1497G>A p.M499I | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.1); catalogued as COSV67241089; called by muse, mutect2, varscan2
- GALNT17 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1315864683, COSV61149103, COSV61154984; called by muse, mutect2, varscan2
- GAPDH | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV57520384, COSV57522234; called by muse, mutect2, varscan2
- GARRE1 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV55104761; called by muse, mutect2, varscan2
- GCHFR | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1355706914, COSV99549203; called by muse, mutect2, varscan2
- GCN1 | c.4835C>T p.S1612F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56115549; called by muse, mutect2, varscan2
- GFRAL | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV61229115; called by muse, mutect2, varscan2
- GIMAP4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV55434967; called by muse, mutect2, varscan2
- GIPC2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs138793126, COSV100883246; called by muse, mutect2, varscan2
- GJA1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV56999828; called by muse, mutect2, varscan2
- GLP1R | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs754315702, COSV64716567; called by muse, mutect2, varscan2
- GML | c.389A>T p.E130V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55278769; called by muse, mutect2, varscan2
- GPBP1 | c.140A>T p.H47L | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV53315119; called by muse, mutect2, varscan2
- GPC2 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs1044936401, COSV52784865; called by muse, mutect2, varscan2
- GPCPD1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV66831929; called by muse, mutect2, varscan2
- GPR158 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391900493, COSV66266132; called by muse, mutect2, varscan2
- GPX6 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62658841; called by muse, mutect2, varscan2
- GRIN2A | c.1747G>A p.G583R | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295182898, COSV58058430; called by muse, mutect2, varscan2
- GRIN2A | c.415-1G>A p.X139_splice | Splice Site (SNP) | VAF 23/43 reads (53%) | catalogued as COSV100408474, COSV58058435; called by muse, mutect2, varscan2
- GRIN3A | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV62458981; called by muse, mutect2, varscan2
- GSTA2 | c.422A>G p.K141R | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.609); catalogued as rs1324801373, COSV72415630; called by muse, varscan2
- GTF2IRD2B | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs782149057, COSV100441306; called by muse, mutect2, varscan2
- GTPBP2 | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs752132566, COSV61077471; called by muse, mutect2, varscan2
- GTSE1 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV71889933; called by muse, mutect2, varscan2
- GUCY1A1 | c.1786C>T p.L596F | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56650600, COSV56656988; called by muse, mutect2, varscan2
- H2BC10 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs774417051, COSV59953151; called by muse, mutect2, varscan2
- HAS3 | c.1049G>A p.W350* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV54709459; called by muse, mutect2, varscan2
- HDAC4 | c.1966C>T p.L656F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61877852; called by muse, mutect2, varscan2
- HDLBP | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60501561; called by muse, mutect2, varscan2
- HEATR1 | c.5113A>T p.K1705* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as COSV63983376; called by muse, mutect2, varscan2
- HEATR5A | c.3644C>T p.S1215F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV66346204; called by muse, mutect2, varscan2
- HELZ2 | c.3028C>T p.R1010C (on ENST00000467148 / NM_001037335.2; = p.R441C on NM_033405.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs570101866, COSV100915519, COSV64409424; called by muse, mutect2
- HERC2 | c.10421C>T p.S3474F | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55305459; called by muse, mutect2, varscan2
- HIRA | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54272274; called by muse, mutect2, varscan2
- HORMAD2 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60901137; called by muse, mutect2, varscan2
- HRC | c.588_589insAAG p.E196_E197insK | In Frame Ins (INS) | VAF 43/57 reads (75%) | catalogued as COSV53255552; called by mutect2, pindel, varscan2
- HS3ST4 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV58806132; called by muse, mutect2, varscan2
- HSD17B4 | c.1063C>T p.Q355* (on ENST00000414835 / NM_001199291.3; = p.Q330* on NM_000414.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV56339553; called by muse, mutect2, varscan2
- HTR1E | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | catalogued as COSV59508267; called by muse, mutect2, varscan2
- HTR1F | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.332); catalogued as rs769604315, COSV60391444; called by muse, mutect2, varscan2
- HTT | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1303509203, COSV61870425; called by muse, mutect2, varscan2
- HYDIN | c.7669G>A p.E2557K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as rs267604619, COSV59263830; called by muse, mutect2
- IFI44L | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs370772828; called by muse, mutect2, varscan2
- IFT122 | c.2522A>T p.H841L (on ENST00000348417 / NM_052989.3; = p.H782L on NM_018262.4) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as COSV56208991; called by muse, mutect2, varscan2
- IGBP1 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.91); PolyPhen benign (0.018); catalogued as COSV60557496; called by muse, mutect2, varscan2
- IGF2R | c.3863C>T p.P1288L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs751227852, COSV100808396, COSV63632930; called by muse, mutect2, varscan2
- IGFBP3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as COSV99298241; called by muse, mutect2, varscan2
- IGHE | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781864663; called by muse, mutect2, varscan2
- IGHV3-11 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 98/191 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.698); catalogued as rs781966817; called by muse, varscan2
- INO80D | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68960231; called by muse, mutect2, varscan2
- INSYN2A | c.490G>C p.A164P | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.706); catalogued as COSV54762443; called by muse, mutect2, varscan2
- INTS8 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 242/597 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV58249346; called by muse, mutect2, varscan2
- IP6K3 | c.620A>C p.Q207P | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV53392160; called by muse, mutect2, varscan2
- IQCH | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs201543259, COSV60055623; called by muse, mutect2, varscan2
- IQGAP2 | c.4231C>T p.R1411C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768773573, COSV57169603; called by muse, mutect2, varscan2
- IRAK4 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs765736285, COSV71211053; called by muse, mutect2, varscan2
- IRF8 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1335070725, COSV51900891, COSV99235948; called by muse, mutect2, varscan2
- ISX | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs200292559; called by muse, mutect2, varscan2
- ITGA4 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV67899245; called by muse, mutect2, varscan2
- ITGA8 | c.2168T>C p.M723T | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV65237068; called by muse, mutect2, varscan2
- ITPRID1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177823377, COSV60079885; called by muse, mutect2, varscan2
- JADE1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368841964, COSV56909721; called by muse, mutect2, varscan2
- KCNA2 | c.1448C>T p.T483I | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.09); catalogued as rs976339794, COSV60371642; called by muse, mutect2, varscan2
- KCNA6 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV54976250, COSV54978325; called by muse, mutect2, varscan2
- KCNB1 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV65571196; called by muse, mutect2, varscan2
- KCND2 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.862); catalogued as rs761446789, COSV58602956; called by muse, mutect2, varscan2
- KCNH5 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV100526719, COSV59777552, COSV59780024; called by muse, mutect2, varscan2
- KCNH5 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV100526477, COSV59760791; called by muse, mutect2, varscan2
- KCNH7 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs946740260, COSV59815460; called by muse, mutect2, varscan2
- KCNJ6 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.782); catalogued as COSV55724237; called by muse, mutect2, varscan2
- KCNK16 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs780255730, COSV100949352; called by muse, varscan2
- KCNK9 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV57289093; called by muse, mutect2, varscan2
- KCNT2 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54086141; called by muse, mutect2, varscan2
- KCTD11 | c.617C>T p.P206L (on ENST00000333751 / NM_001363642.1; = p.P167L on NM_001002914.2) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50142796; called by muse, mutect2, varscan2
- KDM4B | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50270755; called by muse, mutect2, varscan2
- KDM5A | c.3631C>T p.L1211F | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66996704; called by muse, mutect2, varscan2
- KDR | c.3342A>C p.E1114D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55777683; called by muse, mutect2, varscan2
- KDSR | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV100430228, COSV58508385; called by muse, mutect2, varscan2
- KHDRBS2 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as COSV55495434; called by muse, mutect2, varscan2
- KIAA0753 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV63819072; called by muse, mutect2, varscan2
- KIAA1109 | c.3986A>T p.Y1329F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as COSV52680542, COSV52695429; called by muse, mutect2, varscan2
- KIF17 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs749874856, COSV56122991; called by muse, mutect2, varscan2
- KIF25 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63029177; called by muse, mutect2, varscan2
- KIF2B | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | catalogued as COSV99276428; called by muse, mutect2, varscan2
- KIF2B | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52136049; called by muse, mutect2, varscan2
- KIF4B | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs372387001; called by muse, mutect2, varscan2
- KIF7 | c.2688C>G p.N896K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.7); catalogued as COSV67999703; called by muse, mutect2, varscan2
- KLF3 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV54712853; called by muse, mutect2, varscan2
- KLHDC7A | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV68770081; called by muse, mutect2, varscan2
- KLHL13 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV53247863; called by muse, mutect2, varscan2
- KMT2A | c.8819C>T p.T2940I | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as COSV63293219; called by muse, mutect2, varscan2
- KNG1 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV53981402; called by muse, mutect2, varscan2
- KPNA3 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs1305066063, COSV55507722, COSV99079495; called by muse, mutect2, varscan2
- KRT2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs1167029215, COSV59009612; called by muse, mutect2, varscan2
- KRT33A | c.351C>T p.I117= | Splice Region (SNP) | VAF 19/37 reads (51%) | catalogued as COSV50377111; called by muse, mutect2, varscan2
- KRT9 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | PolyPhen benign (0.013); catalogued as COSV55851549; called by muse, mutect2, varscan2
- KRTAP1-1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs868186164, COSV60399291; called by muse, mutect2, varscan2
- KTN1 | c.2606T>A p.L869* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100783289; called by muse, mutect2
- LACC1 | c.533T>C p.L178S | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV57829992; called by muse, mutect2, varscan2
- LAMA2 | c.4646G>A p.R1549Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs778508100, COSV70356171; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA3 | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV58082059; called by muse, mutect2, varscan2
- LAMA3 | c.7115G>A p.R2372K (on ENST00000313654 / NM_198129.4; = p.R763K on NM_000227.6) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.843); catalogued as rs886946683, COSV52544384; called by muse, mutect2, varscan2
- LAP3 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as rs1381460901, COSV56902023; called by muse, mutect2, varscan2
- LCE1F | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.996); catalogued as COSV100542674, COSV57670371; called by muse, mutect2, varscan2
- LEPR | c.3086G>A p.W1029* | Nonsense Mutation (SNP) | VAF 53/115 reads (46%) | catalogued as COSV62752554; called by muse, mutect2, varscan2
- LFNG | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 45/337 reads (13%) | catalogued as COSV67865145; called by muse, mutect2, varscan2
- LGI2 | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1230561623, COSV66122565; called by muse, mutect2, varscan2
- LHCGR | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54303912; called by muse, mutect2, varscan2
- LMBR1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV100626905; called by muse, mutect2, varscan2
- LMX1A | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.886); catalogued as rs150222420; called by muse, mutect2, varscan2
- LONRF2 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV66541001; called by muse, mutect2, varscan2
- LPA | c.4217G>A p.G1406E | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV60313757; called by muse, mutect2, varscan2
- LPA | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV60313770; called by muse, mutect2, varscan2
- LRCH2 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.527); catalogued as COSV57746528, COSV57761180; called by muse, mutect2, varscan2
- LRP1B | c.11620C>T p.Q3874* | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as COSV67213919; called by muse, mutect2, varscan2
- LRP1B | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67279899; called by muse, mutect2, varscan2
- LRP2 | c.12902G>A p.G4301E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV55577254, COSV99788647; called by muse, mutect2, varscan2
- LRP2 | c.3864G>A p.W1288* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV55571788, COSV55577266; called by muse, mutect2, varscan2
- LRRC49 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs201043720, COSV53013287, COSV53016222; called by muse, mutect2, varscan2
- LRRC4C | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as COSV53439199; called by muse, mutect2, varscan2
- LRRCC1 | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs1350574554, COSV64486172; called by muse, mutect2, varscan2
- LRRK2 | c.6115C>T p.R2039C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200765656, COSV54173147; called by muse, mutect2, varscan2
- LRRTM4 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 54/109 reads (50%) | catalogued as rs1421250034, COSV69183154; called by muse, mutect2, varscan2
- LRTM1 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV55586135; called by muse, mutect2, varscan2
- LTBP1 | c.1428G>A p.V476= (on ENST00000404816 / NM_206943.4; = p.V150= on NM_000627.4) | Splice Region (SNP) | VAF 29/64 reads (45%) | catalogued as COSV63198772; called by muse, mutect2, varscan2
- LTBP2 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000800, COSV56214876; called by muse, mutect2, varscan2
- LTF | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51612564; called by muse, mutect2, varscan2
- LUM | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs143511085; called by muse, mutect2, varscan2
- LVRN | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1375202441, COSV63498574; called by muse, mutect2, varscan2
- LYST | c.4175C>A p.S1392* | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | catalogued as COSV67714977; called by muse, mutect2, varscan2
- MACF1 | c.4102C>T p.P1368S | Missense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as COSV58405941; called by muse, mutect2, varscan2
- MACF1 | c.8869G>A p.E2957K | Missense Mutation (SNP) | VAF 31/36 reads (86%) | catalogued as COSV57147157; called by muse, mutect2, varscan2
- MACF1 | c.18862C>A p.L6288I (on ENST00000372915; = p.L4333I on NM_012090.5) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV57147168; called by muse, mutect2, varscan2
- MACROD2 | c.1135G>A p.E379K (on ENST00000642719; = p.E351K on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV54062180; called by muse, mutect2
- MAGEA12 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as COSV63295564; called by muse, mutect2, varscan2
- MAGEB10 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.1); PolyPhen benign (0.302); catalogued as COSV63312832; called by muse, mutect2, varscan2
- MAGEC1 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 98/162 reads (60%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.608); catalogued as COSV53582441; called by muse, varscan2
- MAGEL2 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); catalogued as COSV58569399; called by muse, mutect2, varscan2
- MAGEL2 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.087); catalogued as COSV58569414; called by muse, mutect2
- MAP2 | c.4894C>T p.P1632S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52309808, COSV99561161; called by muse, mutect2, varscan2
- MAP3K5 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as rs866248186, COSV62891457; called by muse, mutect2, varscan2
- MAP3K7 | c.1552G>A p.E518K (on ENST00000369329 / NM_145331.3; = p.E491K on NM_003188.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV65226261; called by muse, mutect2, varscan2
- MAPK1IP1L | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.382); catalogued as rs771559540, COSV67106293, COSV67106614; called by muse, mutect2, varscan2
- MAPK7 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1428148784, COSV55192069; called by muse, mutect2, varscan2
- MASP2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs201990552; called by muse, mutect2, varscan2
- MAST3 | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1439031862, COSV53224125; called by muse, mutect2, varscan2
- MC2R | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59620721; called by muse, mutect2, varscan2
- MCHR2 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as rs200729735, COSV56003624, COSV56009898; called by muse, mutect2, varscan2
- MDFIC | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV57568017; called by muse, mutect2, varscan2
- MEGF10 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV99175809; called by muse, mutect2, varscan2
- MEGF10 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV57250868, COSV99175813; called by muse, mutect2, varscan2
- MEIOC | c.1759G>A p.G587R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.34); catalogued as rs769551948, COSV63440552; called by muse, mutect2, varscan2
- MEIOC | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV63440559; called by muse, mutect2, varscan2
- MEPE | c.1408C>T p.H470Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1378723644, COSV63073912; called by muse, mutect2, varscan2
- METTL3 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV52967817; called by muse, mutect2, varscan2
- MFSD2A | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65686705; called by muse, mutect2, varscan2
- MGA | c.7625C>T p.P2542L (on ENST00000219905 / NM_001164273.1; = p.P2333L on NM_001080541.2) | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54949645; called by muse, mutect2, varscan2
- MGAM | c.3049G>A p.A1017T | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV72075999; called by muse, mutect2, varscan2
- MGAT4C | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1038806292, COSV59838479; called by muse, mutect2, varscan2
- MLKL | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV58205008, COSV58206111; called by muse, mutect2, varscan2
- MLPH | c.1312A>T p.T438S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV52824604; called by muse, mutect2, varscan2
- MMP1 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV59510909; called by muse, mutect2
- MMP14 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV61289780; called by muse, mutect2, varscan2
- MMP26 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV56173868; called by muse, mutect2, varscan2
- MORC1 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51718133; called by muse, mutect2, varscan2
- MORC1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs867776552, COSV51718259; called by muse, mutect2, varscan2
- MORN3 | c.226A>C p.T76P | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV62507885; called by muse, mutect2, varscan2
- MPP7 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV61738964; called by muse, mutect2, varscan2
- MPPED2 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV100813309, COSV63901577; called by muse, mutect2, varscan2
- MRGPRX1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as rs1364627192, COSV57106743; called by muse, mutect2, varscan2
- MRPL2 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs780252724, COSV52439582; called by muse, mutect2, varscan2
- MS4A2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV54014048; called by muse, mutect2, varscan2
- MSH4 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as rs754511661, COSV54213640; called by muse, mutect2, varscan2
- MSR1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV50540000; called by muse, mutect2, varscan2
- MSR1 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.291); catalogued as COSV50540211; called by muse, mutect2, varscan2
- MSR1 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV50540412; called by muse, mutect2, varscan2
- MST1R | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.523); catalogued as COSV56574620; called by muse, mutect2, varscan2
- MTF1 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 176/208 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV65990779; called by muse, mutect2, varscan2
- MUC16 | c.20892T>A p.F6964L | Missense Mutation (SNP) | VAF 160/171 reads (94%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.02); catalogued as COSV67497933; called by muse, mutect2, varscan2
- MUC16 | c.13364C>T p.S4455F | Missense Mutation (SNP) | VAF 76/85 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV67493331; called by muse, mutect2, varscan2
- MUC17 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV60284038; called by muse, mutect2, varscan2
- MUC17 | c.9431C>T p.S3144L | Missense Mutation (SNP) | VAF 124/315 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV60305670; called by muse, mutect2, varscan2
- MYBL2 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1481851115, COSV53834160; called by muse, mutect2, varscan2
- MYCN | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55261624; called by muse, mutect2, varscan2
- MYD88 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100086542; called by muse, mutect2, varscan2
- MYH1 | c.2786G>A p.R929K | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV99877051; called by muse, mutect2, varscan2
- MYH2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55449950; called by muse, mutect2, varscan2
- MYH4 | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV55117180; called by muse, mutect2, varscan2
- MYO16 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779048736, COSV51821109; called by muse, mutect2, varscan2
- MYO18B | c.6323G>A p.R2108Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs761193684, COSV59142649; called by muse, mutect2, varscan2
- MYO3B | c.1588A>C p.N530H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58719791; called by muse, mutect2
- MYO5B | c.4502C>T p.P1501L | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV53232837; called by muse, mutect2, varscan2
- MYO7A | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV68686252; called by muse, mutect2, varscan2
- MYO7B | c.5246C>T p.P1749L | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV67352513; called by muse, mutect2, varscan2
- MYO9A | c.6466C>T p.R2156* | Nonsense Mutation (SNP) | VAF 51/92 reads (55%) | catalogued as rs145598484; called by muse, mutect2, varscan2
- MYOCD | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs267604740, COSV58502220; called by muse, mutect2, varscan2
- MZF1 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV53043463; called by muse, mutect2, varscan2
- NAALAD2 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58966757; called by muse, mutect2
- NAALAD2 | c.1196-1G>A p.X399_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV58966763; called by muse, mutect2, varscan2
- NAALADL2 | c.2127T>A p.N709K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71987148; called by muse, mutect2, varscan2
- NAP1L2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.84); catalogued as COSV65172399, COSV65172992; called by muse, mutect2, varscan2
- NCAPG2 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51992305; called by muse, mutect2, varscan2
- NCKAP5 | c.449A>C p.E150A | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as COSV58478295; called by muse, mutect2, varscan2
- NCOA7 | c.1752A>T p.K584N | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.15); catalogued as COSV57660893; called by muse, mutect2, varscan2
- NDUFA10 | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV53156879; called by muse, mutect2, varscan2
- NF1 | c.3821T>A p.L1274H | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV62223512; called by muse, mutect2, varscan2
- NFATC4 | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.241); catalogued as rs752964036, COSV51612931; called by muse, mutect2, varscan2
- NFKB1 | c.1234C>T p.P412S (on ENST00000394820 / NM_001382627.1; = p.P413S on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs1163517867, COSV56961425; called by muse, mutect2, varscan2
- NLRC5 | c.4291C>T p.Q1431* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52662521; called by muse, mutect2, varscan2
- NLRP1 | c.907T>A p.Y303N | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52579926; called by muse, mutect2, varscan2
- NLRP10 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV60778583; called by muse, mutect2, varscan2
- NLRP8 | c.2155T>G p.F719V | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV52594725; called by muse, mutect2, varscan2
- NMS | c.450G>A p.Q150= | Splice Region (SNP) | VAF 9/20 reads (45%) | catalogued as COSV65258546; called by muse, mutect2, varscan2
- NOBOX | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56198213; called by muse, varscan2
- NOS1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV57611927; called by muse, mutect2, varscan2
- NOTCH3 | c.4690G>T p.G1564C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV54652750; called by muse, mutect2
- NOTCH4 | c.3529G>A p.G1177R | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); catalogued as rs1311098727, COSV66682232; called by muse, mutect2, varscan2
- NPC1 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs1555637232, COSV52579221; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NPIPB15 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV70438782; called by mutect2, varscan2
- NPTN | c.1032G>T p.L344F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54740388; called by muse, mutect2, varscan2
- OR10G8 | c.212T>A p.F71Y | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV70909542; called by muse, mutect2, varscan2
- OR10K1 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 66/112 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1461483065, COSV56872271; called by muse, varscan2
- OR10K2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV59222973; called by muse, mutect2, varscan2
- OR11A1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs745945077, COSV65820876; called by muse, mutect2
- OR14A16 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62927592; called by muse, mutect2, varscan2
- OR1A1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.02); catalogued as rs1300345102, COSV58403205; called by muse, mutect2, varscan2
- OR2J2 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65848449; called by muse, mutect2, varscan2
- OR2Y1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757690361, COSV100322702, COSV57137757; called by muse, mutect2, varscan2
- OR3A1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60163936; called by muse, mutect2, varscan2
- OR4A15 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV59034598, COSV59035155; called by muse, mutect2, varscan2
- OR4B1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58884086; called by muse, mutect2, varscan2
- OR4C16 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs201027271, COSV58944568; called by muse, mutect2, varscan2
- OR4C6 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as rs746616835, COSV58603591, COSV58605102, COSV58606600; called by muse, mutect2, varscan2
- OR4D10 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV73260221; called by muse, mutect2, varscan2
- OR4K13 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183363473, COSV59859288; called by muse, mutect2, varscan2
- OR4K14 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100520475, COSV59293883; called by muse, mutect2, varscan2
- OR4M1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs760327097, COSV60059765, COSV60060322, COSV60060528; called by muse, mutect2, varscan2
- OR51A7 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63789058; called by muse, mutect2, varscan2
- OR51F2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs767787431, COSV59063793; called by muse, mutect2, varscan2
- OR51S1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 49/105 reads (47%) | catalogued as rs200652284, COSV59057683; called by muse, mutect2, varscan2
- OR52D1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs746533430, COSV59487372; called by muse, mutect2, varscan2
- OR52E8 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV66213306; called by muse, mutect2, varscan2
- OR52K2 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57835919; called by muse, mutect2, varscan2
- OR5B2 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV56909878; called by muse, mutect2, varscan2
- OR5B3 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV58678855; called by muse, mutect2, varscan2
- OR5J2 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.572); catalogued as COSV56623516; called by muse, mutect2, varscan2
- OR6C68 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs575378437, COSV65564038; called by muse, mutect2, varscan2
- OR8B4 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as COSV62070687; called by muse, mutect2, varscan2
- OR8D1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63443161; called by muse, mutect2, varscan2
- OR8S1 | c.164T>A p.L55H | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59600979; called by muse, mutect2, varscan2
- OTOF | c.2471A>G p.K824R (on ENST00000272371 / NM_194248.3; = p.K77R on NM_004802.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55522261, COSV55524042; called by muse, mutect2, varscan2
- OTOF | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs200279237, COSV55522289; called by muse, mutect2, varscan2
- OXR1 | c.541C>T p.H181Y (on ENST00000442977 / NM_001198532.1; = p.H180Y on NM_018002.3) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as COSV56337224; called by muse, mutect2, varscan2
- PAK5 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs867360779, COSV100781221, COSV62030929; called by muse, mutect2, varscan2
- PAPPA2 | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.131); catalogued as COSV100867755, COSV62813731; called by muse, mutect2, varscan2
- PAPPA2 | c.2966A>C p.E989A | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV100868768; called by muse, mutect2, varscan2
- PAPPA2 | c.3172G>A p.D1058N | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.27); catalogued as rs1353166778, COSV62793572; called by muse, mutect2, varscan2
- PARP12 | c.1879T>C p.F627L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV54937511; called by muse, mutect2, varscan2
- PARP15 | c.2011G>A p.E671K (on ENST00000464300 / NM_001113523.3; = p.E437K on NM_152615.2) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59975342; called by muse, mutect2, varscan2
- PARVB | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV58692087; called by muse, mutect2, varscan2
- PBX1 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63345788, COSV63348552; called by muse, mutect2, varscan2
- PBX3 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV60736530; called by muse, mutect2, varscan2
- PCDH19 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55272520; called by muse, mutect2, varscan2
- PCDH8 | c.2947C>T p.Q983* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as COSV58815257; called by muse, mutect2, varscan2
- PCDHA4 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.028); catalogued as rs781791401, COSV63538555; called by muse, mutect2, varscan2
- PCDHA7 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65343964; called by mutect2, varscan2
- PCDHA9 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65327070; called by muse, mutect2, varscan2
- PCDHAC1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1227240979, COSV53838474; called by muse, mutect2, varscan2
- PCDHAC1 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV53872655; called by muse, mutect2, varscan2
- PCDHAC2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.022); catalogued as COSV53871107; called by muse, mutect2, varscan2
- PCDHB1 | c.1703A>G p.N568S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV60633596; called by muse, mutect2, varscan2
- PCDHB9 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs1315810965, COSV53379024; called by muse, mutect2, varscan2
- PCDHGB2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.17); catalogued as COSV54003645; called by muse, mutect2, varscan2
- PCDHGB2 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs1242362767, COSV54044453; called by muse, mutect2, varscan2
- PCNT | c.7357C>T p.L2453F | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745674872, COSV100856111; called by muse, mutect2, varscan2
- PCSK1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as rs770310795, COSV60734749, COSV60737225; called by muse, mutect2, varscan2
- PDE1A | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs770985972, COSV59515206; called by muse, mutect2, varscan2
- PDGFRA | c.2663T>A p.I888N | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57270349; called by muse, mutect2, varscan2
- PEG10 | c.259G>A p.D87N (on ENST00000482108 / NM_001040152.2; = p.D121N on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV71788728; called by muse, mutect2, varscan2
- PENK | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs148519224, COSV59240758; called by muse, mutect2, varscan2
- PGLYRP3 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 84/146 reads (58%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV51953200; called by muse, mutect2, varscan2
- PHLPP2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs762882143, COSV62423892; called by muse, mutect2, varscan2
- PITPNM1 | c.2905C>T p.H969Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54161622; called by muse, mutect2, varscan2
- PKHD1L1 | c.4300G>A p.G1434R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); catalogued as COSV65754698; called by muse, mutect2, varscan2
- PLA2G4E | c.2304G>A p.M768I | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs762971733, COSV68149710; called by muse, mutect2, varscan2
- PLAGL2 | c.1097T>A p.L366H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV55789974; called by muse, mutect2, varscan2
- PLCG2 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs867804190, COSV63877281; called by muse, mutect2, varscan2
- PLCG2 | c.3247C>T p.P1083S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100842647, COSV63876169; called by muse, mutect2, varscan2
- PLCZ1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.469); catalogued as COSV56852116; called by muse, mutect2, varscan2
- PLD1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV60574796; called by muse, mutect2, varscan2
- PLSCR4 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.371); catalogued as COSV61609160; called by muse, mutect2, varscan2
- PMM2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765433263, CM043063, COSV51631340; ClinVar: uncertain significance; called by muse, mutect2
- PPIAL4G | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 113/189 reads (60%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.084); catalogued as rs1196181037, COSV70086977, COSV70087116; called by muse, mutect2, varscan2
- PRDM14 | c.608A>C p.H203P | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV52575685; called by muse, mutect2, varscan2
- PRKAG2 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55242917; called by muse, mutect2, varscan2
- PRKAG3 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV52103508; called by muse, mutect2, varscan2
- PRM2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.147); catalogued as rs775204728, COSV54114065; called by muse, mutect2, varscan2
- PROX2 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV71520233; called by muse, mutect2, varscan2
- PRR14L | c.5593T>G p.S1865A | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV57888445; called by muse, mutect2, varscan2
- PSD3 | c.2836G>A p.E946K (on ENST00000440756; = p.E945K on NM_015310.4) | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs745313487, COSV54081558; called by muse, mutect2, varscan2
- PSD3 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58980619; called by muse, mutect2, varscan2
- PTPN14 | c.2845C>T p.R949* | Nonsense Mutation (SNP) | VAF 57/86 reads (66%) | catalogued as rs962347314, COSV65283337; called by muse, mutect2, varscan2
- PTPRK | c.2440G>A p.E814K (on ENST00000368215 / NM_001291984.2; = p.E815K on NM_002844.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as COSV100950471, COSV63908372; called by muse, mutect2, varscan2
- PTPRK | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327332012, COSV63888725; called by muse, mutect2, varscan2
- PTPRK | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.381); catalogued as COSV63888732; called by muse, mutect2, varscan2
- PTPRR | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV51749491; called by muse, mutect2, varscan2
- PYCR1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1053110486, COSV58000259; called by muse, mutect2, varscan2
- QRFP | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV58065210; called by muse, mutect2, varscan2
- QRICH1 | c.2139-1G>A p.X713_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100455223; called by muse, mutect2
- QRSL1 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1459826799, COSV64688190; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3776T>C p.L1259P (on ENST00000330843 / NM_001002814.3; = p.L625P on NM_025151.5) | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54764521; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1251T>A p.D417E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51489618; called by muse, mutect2, varscan2
- RAG2 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV57557056; called by muse, mutect2, varscan2
- RAPGEF2 | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as COSV52434284; called by muse, mutect2
- RAPGEF4 | c.2288G>A p.G763E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV51396578; called by muse, mutect2, varscan2
- RASGRP2 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs371237302; called by muse, mutect2, varscan2
- RBBP8NL | c.1370A>C p.K457T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV53351344; called by muse, mutect2
- RBBP8NL | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs1379343219, COSV53351355; called by muse, mutect2, varscan2
- RBCK1 | c.1472G>A p.G491E (on ENST00000356286 / NM_031229.4; = p.G449E on NM_006462.6) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1250230052, COSV62293460; called by muse, mutect2, varscan2
- RD3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.463); catalogued as COSV65361967; called by muse, mutect2
- RECQL5 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV53130530; called by muse, mutect2, varscan2
- RERGL | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57463854; called by muse, mutect2, varscan2
- RHBDF1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV51958396; called by muse, mutect2, varscan2
- RIMS2 | c.1532C>T p.S511L (on ENST00000666250 / NM_001348490.2; = p.S319L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51650842; called by muse, mutect2, varscan2
- RIMS2 | c.3016C>T p.R1006C (on ENST00000666250 / NM_001348490.2; = p.R814C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs752258688, COSV51728682; called by muse, mutect2, varscan2
- RIPOR3 | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 29/64 reads (45%) | catalogued as COSV50407184; called by muse, mutect2, varscan2
- RNF145 | c.1975C>T p.P659S (on ENST00000424310 / NM_001199383.2; = p.P687S on NM_144726.2) | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV50874363; called by muse, mutect2, varscan2
- RNF25 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV55309920; called by muse, mutect2, varscan2
- RNF38 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV52397668, COSV99424829; called by muse, mutect2, varscan2
- RP1 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV55111640; called by muse, varscan2
- RP1L1 | c.4841G>A p.R1614Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as rs563706341, COSV66759083; called by muse, mutect2
- RPL39L | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV56220440; called by muse, mutect2, varscan2
- RPL7L1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs199719364, COSV59034828; called by muse, varscan2
- RPS15 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 53/60 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV51836603, COSV99245352; called by muse, mutect2, varscan2
- RPTN | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV60169417; called by muse, mutect2, varscan2
- RPTN | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 513/874 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV60169424; called by muse, mutect2, varscan2
- RRAD | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.626); catalogued as COSV55340133; called by muse, mutect2, varscan2
- RYR2 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV63718097; called by muse, mutect2, varscan2
- S100A12 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.905); catalogued as rs933777006, COSV64199395; called by muse, mutect2, varscan2
- SAGE1 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT tolerated (0.62); PolyPhen benign (0.159); catalogued as COSV61018683; called by muse, mutect2, varscan2
- SATL1 | c.886G>A p.E296K (on ENST00000395409; = p.E483K on NM_001012980.2) | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as rs1161475320, COSV60575587; called by muse, mutect2, varscan2
- SCGN | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV58547382; called by muse, mutect2, varscan2
- SCML2 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs757028343, COSV52625428; called by muse, mutect2, varscan2
- SCN11A | c.3980A>T p.E1327V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV56579383; called by muse, mutect2, varscan2
- SCN5A | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV61138619; called by muse, mutect2, varscan2
- SDK2 | c.6209C>T p.A2070V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV66198163; called by muse, mutect2, varscan2
- SEL1L2 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53159002; called by muse, mutect2, varscan2
- SEL1L3 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV53550454, COSV99341185; called by muse, mutect2, varscan2
- SEMA4C | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV59692541; called by muse, mutect2, varscan2
- SERPINA3 | c.1079A>G p.K360R | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.274); catalogued as COSV67587302; called by muse, mutect2, varscan2
- SERPINB13 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs138290904; called by muse, mutect2, varscan2
- SERPINB4 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as COSV61984877; called by muse, mutect2, varscan2
- SERPINF2 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs769851018, COSV60665898; called by muse, mutect2, varscan2
- SERPINI2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV52984441; called by muse, mutect2, varscan2
- SEZ6L2 | c.1432G>T p.D478Y (on ENST00000308713 / NM_001114099.3; = p.D408Y on NM_012410.4) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV58104868; called by muse, mutect2
- SFXN4 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53720559; called by muse, mutect2, varscan2
- SGCZ | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV65994859; called by muse, mutect2, varscan2
- SGO1 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs373453727; called by muse, varscan2
- SH3BP1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100379399; called by muse, varscan2
- SH3RF1 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV52925712; called by muse, mutect2, varscan2
- SHC4 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60114528; called by muse, mutect2, varscan2
- SIDT1 | c.2446C>T p.L816F | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1326816494, COSV53508035; called by muse, mutect2, varscan2
- SIGLEC1 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.145); catalogued as COSV52474159; called by muse, mutect2, varscan2
- SLA2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs369794434; called by muse, mutect2, varscan2
- SLC11A1 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV51920015; called by muse, mutect2, varscan2
- SLC16A5 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866291818, COSV61677110; called by muse, mutect2
- SLC22A2 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs371692503; called by muse, mutect2, varscan2
- SLC22A8 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1380439989, COSV60327385; called by muse, mutect2, varscan2
- SLC26A2 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.044); catalogued as COSV53824725; called by muse, mutect2
- SLC38A6 | c.1171A>T p.I391F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV50786693; called by muse, mutect2, varscan2
- SLC44A5 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs746817323, COSV63775599; called by muse, mutect2, varscan2
- SLC5A1 | c.136-1G>A p.X46_splice | Splice Site (SNP) | VAF 91/229 reads (40%) | catalogued as rs267606230, COSV56689278; called by muse, mutect2, varscan2
- SLC5A10 | c.1787C>T p.A596V (on ENST00000395645 / NM_001042450.4; = p.A612V on NM_152351.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1298794020, COSV52414647; called by muse, mutect2, varscan2
- SLC6A13 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1451644014, COSV58255704, COSV58260885; called by muse, mutect2, varscan2
- SLC6A13 | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.019); catalogued as COSV100570098; called by muse, mutect2, varscan2
- SLC6A19 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58674983; called by muse, mutect2, varscan2
- SLC9C2 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.903); catalogued as COSV62944851, COSV62945360, COSV62947526; called by muse, mutect2, varscan2
- SLCO6A1 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65806914; called by muse, mutect2, varscan2
- SLFN13 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53195965; called by muse, mutect2, varscan2
- SLITRK1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV65676811; called by muse, mutect2, varscan2
- SMAD6 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs1411788691, COSV56598030; called by muse, mutect2, varscan2
- SMR3B | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV59229499; called by muse, mutect2, varscan2
- SNCAIP | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1202447814, COSV54420504; called by muse, mutect2, varscan2
- SORBS1 | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.031); catalogued as rs377236017, COSV53366865; called by muse, mutect2, varscan2
- SORL1 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758683402, COSV52763619; called by muse, mutect2, varscan2
- SP140 | c.452T>G p.L151* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV59455731; called by muse, mutect2, varscan2
- SPANXN2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 185/270 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV65129662; called by muse, varscan2
- SPATA31E1 | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs778879521, COSV57795812; called by muse, mutect2, varscan2
- SPHK2 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 144/159 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs769178157, COSV55342508; called by muse, mutect2, varscan2
- SPHKAP | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs775866234, COSV60871291, COSV60892119; called by muse, mutect2, varscan2
- SPTA1 | c.3869A>T p.K1290I | Missense Mutation (SNP) | VAF 99/169 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs746792343, COSV63752529, COSV63760583; called by muse, mutect2, varscan2
- SRD5A2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as COSV99252644; called by muse, mutect2, varscan2
- SSTR4 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.006); catalogued as rs1452446716, COSV54800504; called by muse, mutect2, varscan2
- SSX7 | c.69G>A p.K23= | Splice Region (SNP) | VAF 79/108 reads (73%) | catalogued as COSV53341894; called by muse, mutect2, varscan2
- ST8SIA3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | PolyPhen possibly damaging (0.626); catalogued as COSV60653959; called by muse, mutect2, varscan2
- STAG3 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs745695694, COSV57930420; called by muse, mutect2, varscan2
- STEAP3 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as rs1348234297, COSV100713511; called by muse, mutect2, varscan2
- STOML3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV65512054; called by muse, mutect2, varscan2
- STRA6 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV60588243; called by muse, mutect2, varscan2
- STXBP5L | c.2659G>A p.G887S | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1441539807, COSV56537325; called by muse, mutect2, varscan2
- SUN3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.028); catalogued as COSV52049161; called by muse, mutect2, varscan2
- SUPT6H | c.5023G>A p.G1675R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.879); catalogued as rs770269842, COSV56388930; called by muse, mutect2, varscan2
- SYCE1 | c.856G>A p.G286R (on ENST00000343131 / NM_001143764.3; = p.G250R on NM_130784.3) | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as COSV58216791; called by muse, mutect2, varscan2
- SYCP2L | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV51652625; called by muse, mutect2
- SYNE1 | c.15548G>A p.R5183K (on ENST00000367255 / NM_182961.4; = p.R5112K on NM_033071.3) | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55118103; called by muse, mutect2, varscan2
- SYNJ2BP | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as rs772822266, COSV56445891; called by muse, mutect2, varscan2
- SYT10 | c.252G>A p.W84* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV57346071; called by muse, mutect2, varscan2
- SYTL3 | c.893T>G p.M298R (on ENST00000611299 / NM_001242394.1; = p.M230R on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as COSV51915753; called by muse, mutect2, varscan2
- TARS3 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1376692079, COSV100255071; called by muse, mutect2, varscan2
- TBX15 | c.430C>T p.P144S (on ENST00000369429 / NM_001330677.2; = p.P38S on NM_152380.3) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52868415, COSV52869239; called by muse, mutect2
- TC2N | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV61748369; called by muse, mutect2, varscan2
- TCF4 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV61907184; called by muse, mutect2, varscan2
- TCF4 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV61907193; called by muse, mutect2, varscan2
- TCF7L1 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV56403860; called by muse, mutect2, varscan2
- TCP11 | c.1406A>G p.N469S (on ENST00000512012; = p.N407S on NM_018679.5) | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1241232875, COSV55136402; called by muse, mutect2, varscan2
- TDRD6 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV60174251; called by muse, mutect2, varscan2
- TEF | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56749010; called by muse, mutect2, varscan2
- TELO2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV51981647; called by muse, mutect2, varscan2
- TENM1 | c.6190C>T p.L2064F | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs867628905, COSV100949722, COSV64445087; called by muse, mutect2, varscan2
- TENM4 | c.2178C>T p.I726= | Splice Region (SNP) | VAF 10/20 reads (50%) | catalogued as rs759427227, COSV53630542; called by muse, varscan2
- TEPSIN | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56145168; called by muse, mutect2, varscan2
- TET3 | c.1218G>A p.W406* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV59882814; called by muse, mutect2, varscan2
- TEX55 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs113445078, COSV99817865; called by muse, mutect2, varscan2
- TEX55 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.11); catalogued as COSV99817868; called by muse, mutect2, varscan2
- TH | c.247G>A p.A83T (on ENST00000381178 / NM_199292.3; = p.A52T on NM_000360.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.581); catalogued as COSV60768827; called by muse, mutect2, varscan2
- THSD7A | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70273783; called by muse, mutect2, varscan2
- TLX3 | c.52T>C p.F18L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51542162; called by muse, mutect2, varscan2
- TMC3 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV63924789; called by muse, mutect2, varscan2
- TMEFF2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV55833413; called by muse, mutect2, varscan2
- TMEM132B | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.085); catalogued as rs757718701, COSV54749643; called by muse, mutect2, varscan2
- TMEM132B | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV54772424; called by muse, mutect2, varscan2
- TMEM132B | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV54772433; called by muse, mutect2, varscan2
- TMEM132D | c.2570C>T p.T857I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67162794, COSV99066529; called by muse, mutect2, varscan2
- TMEM132E | c.2605G>A p.E869K (on ENST00000321639; = p.E959K on NM_001304438.2) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV58700927; called by muse, mutect2, varscan2
- TMEM184B | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs780667372, COSV62674458; called by muse, mutect2, varscan2
- TMEM237 | c.909T>A p.F303L (on ENST00000409883 / NM_001044385.3; = p.F295L on NM_152388.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as COSV53807030; called by muse, mutect2, varscan2
- TMPRSS11F | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62469860; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64423432; called by muse, mutect2, varscan2
- TNFRSF9 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV66348974; called by muse, mutect2, varscan2
- TNNC1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs730881064, COSV51768602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNS2 | c.901C>T p.P301S (on ENST00000314250 / NM_170754.4; = p.P311S on NM_015319.2) | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV58582481; called by muse, mutect2, varscan2
- TNXB | c.8468C>T p.T2823I (on ENST00000647633; = p.T2576I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/426 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV64489895; called by muse, mutect2, varscan2
- TPPP2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1363896606, COSV53876273; called by muse, mutect2, varscan2
- TPTE | c.1138G>A p.E380K (on ENST00000618007 / NM_199261.4; = p.E362K on NM_199259.4) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs781489069; called by muse, mutect2, varscan2
- TPTE2 | c.1292G>A p.G431E (on ENST00000400230 / NM_199254.2; = p.G354E on NM_130785.3) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV55027074; called by muse, mutect2
- TPTE2 | c.271C>T p.L91F (on ENST00000400230 / NM_199254.2; = p.L54F on NM_130785.3) | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs1401418891, COSV55017259, COSV55029329; called by muse, mutect2, varscan2
- TRAV24 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.653); catalogued as rs1218015110; called by muse, mutect2, varscan2
- TRIM15 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1176051669, COSV64990543; called by muse, mutect2, varscan2
- TRIM22 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs371139090; called by muse, mutect2, varscan2
- TRIM29 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59282344; called by muse, mutect2, varscan2
- TRIM36 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV56693749; called by muse, mutect2, varscan2
- TRIM58 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV63572486; called by muse, mutect2, varscan2
- TRIM69 | c.1474G>A p.E492K (on ENST00000329464 / NM_182985.5; = p.E333K on NM_080745.5) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV57805530; called by muse, mutect2, varscan2
- TRIOBP | c.3139C>T p.P1047S | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60385166; called by muse, mutect2, varscan2
- TRPC3 | c.697G>A p.D233N (on ENST00000379645 / NM_001366479.2; = p.D160N on NM_003305.2) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53382203; called by muse, mutect2, varscan2
- TRPC4 | c.1245G>A p.W415* | Nonsense Mutation (SNP) | VAF 25/38 reads (66%) | catalogued as COSV100156184, COSV59021082; called by muse, mutect2, varscan2
- TSPAN8 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 144/373 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV56078715; called by muse, mutect2, varscan2
- TTC39B | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV52617516; called by muse, mutect2, varscan2
- TTN | c.66250G>A p.D22084N (on ENST00000591111; = p.D14660N on NM_003319.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | PolyPhen probably damaging (0.998); catalogued as COSV60383453; called by muse, mutect2, varscan2
- TTN | c.61450G>A p.E20484K (on ENST00000591111; = p.E13060K on NM_003319.4) | Missense Mutation (SNP) | VAF 38/108 reads (35%) | PolyPhen probably damaging (0.994); catalogued as rs752675920, COSV59944557; called by muse, mutect2, varscan2
- TTN | c.56455G>A p.E18819K (on ENST00000591111; = p.E11395K on NM_003319.4) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | PolyPhen probably damaging (0.994); catalogued as COSV60383551; called by muse, mutect2, varscan2
- TTN | c.51723C>T p.F17241= (on ENST00000591111; = p.F9817= on NM_003319.4) | Splice Region (SNP) | VAF 105/249 reads (42%) | catalogued as COSV100615453, COSV60383587; called by muse, mutect2, varscan2
- TTN | c.36811G>A p.E12271K (on ENST00000591111; = p.E4847K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | PolyPhen benign (0.42); catalogued as COSV60383631; called by muse, mutect2
- TULP4 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV65581386; called by muse, mutect2, varscan2
- TXK | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs1416853673, COSV51920079; called by muse, mutect2, varscan2
483 further variants in this file (77 protein-altering or splice-affecting, 376 silent, 30 other) are not listed here.
